Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HX, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HX-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. COLON, RIGHT, HEMICOLECTOMY:
High grade leiomyosarcoma. (See Key Pathological Findings).

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Key Pathological Findings

Tumor site:	Right colon
Tumor configuration:	Polypoid and ulcerated
Tumor size:	4.0 x 3.6 x 2.2 cm
Tumor type:	Leiomyosarcoma
Tumor grade:	FNCLCC grade 3/3 (tumor differentiation 2, mitoses 3, necrosis 1 = 6/8)
Tumor involvement:	Mucosa, submucosa, and muscularis propria of right colon
Tumor necrosis:	Less than 50%
Surgical margins:	Proximal, distal, and radial margin are free of tumor
Lymph nodes:	36 regional lymph nodes with reactive changes and no evidence of Malignancy (0/36).
Other findings:	Tubular adenoma, fibrous obliteration of appendiceal tip, lipohyperplasia of ileocecal valve
Pathologic stage:	Not applicable

*Leiomyosarcoma NOS
Site: Retroperitoneum
path Right colon
889013
C48.0
C18.2
JW 4/22/14*

Specimen(s) Received

A RIGHT HEMICOLECTOMY 2 FS

Clinical History

Sarcoma right colon.

Preoperative Diagnosis

None given.

Intraoperative Consultation

[page 2 of 2]
FSA1. PROXIMAL MARGIN:
No evidence of malignancy.

FSA2. DISTAL MARGIN:
No evidence of malignancy.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr. in OR

I, MD, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is received fresh labeled "right hemicolectomy" and consists of a right colon received stapled at both ends. The specimen consists of a 4.0 cm in length, 3.5 cm in circumference segment of small bowel continuous with a 14.0 cm in length, 7.5 cm in circumference segment of large bowel, and an attached 5.0 cm in length, 0.4 cm in diameter vermiform appendix. In the ascending colon is a 4.0 x 3.6 x 2.2 cm pedunculated polypoid mass. The mass is 3.7 cm from the ileocecal valve, 8.5 cm from the distal margin. The mass extends approximately 0.2 cm in the submucosa but does not extend through the bowel wall. The mass is 6.5 cm from the radial soft tissue margin. The mass does not involve the surrounding serosa. There are 2 additional broad-based, sessile polypoid lesions, which are 0.3 and 0.9 cm in greatest dimension. The remaining mucosa has normal tan folds. The wall averages 0.3 cm in thickness. There is an abundant amount of surrounding adipose tissue. The proximal margin is sectioned tangentially, frozen and entirely submitted in FSA1. The distal margin is sectioned tangentially, frozen and entirely submitted in FSA2. Additional representative sections are submitted as follows:

- A3: Ileocecal valve
- A4: Appendix
- A5-A6: Composite section of mass with deepest involvement
- A7-A8: Additional composite section of mass with deepest involvement
- A9-A11: Additional sections of mass
- A12: One additional polyp
- A13: Additional polyp, sectioned
- A14: Normal bowel
- A15: Eight possible lymph nodes
- A16: Ten possible lymph nodes
- A17: Ten possible lymph nodes
- A18: Seven possible lymph nodes
- A19: Three possible lymph nodes
- A20: Two possible lymph nodes

A portion of tissue is submitted to the

Source: NCI Genomic Data Commons file 2355a8fb-882e-438c-908c-7e1ff2023c91 (TCGA-3B-A9HX.8A122318-3A8B-436F-9E9A-326984268B88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).